Somatic mutation profile of tumor specimen 0DSHT5 from CCDI case PBCIDX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 7.0 years (2,548 days).
Specimen 0DSHT5: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aca03713-c9ab-4b95-9a59-19eaf566c253.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSHTG (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fc1c2c5e-51e5-4573-bd43-715138ad7bf4

The open-access MAF lists 20 somatic variants for this specimen: 10 protein-altering or splice-affecting, 5 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 5, 3'Flank 2, 3'UTR 2, Nonsense Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.100G>A p.G34R | Missense Mutation (SNP) | VAF 168/420 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913399, COSV62687911, COSV62687931, COSV62721471; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NIPBL | c.1435C>T p.R479* | Nonsense Mutation (SNP) | VAF 146/561 reads (26%) | catalogued as rs1554015303, CM042507, COSV99243206; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRBA2 | c.883C>T p.R295W | Missense Mutation (SNP) | VAF 283/685 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as rs376563729, COSV58779134; called by muse, mutect2, varscan2
- PCDHGA7 | c.404C>T p.T135M | Missense Mutation (SNP) | VAF 309/564 reads (55%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.026); catalogued as rs1445366017, COSV53934427; called by muse, mutect2, varscan2
- RANBP1 | c.509G>A p.G170E | Missense Mutation (SNP) | VAF 147/344 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as rs759533670; called by muse, mutect2, varscan2
- SOCS6 | c.647T>C p.M216T | Missense Mutation (SNP) | VAF 190/479 reads (40%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0); catalogued as rs567159663; called by muse, mutect2, varscan2
- ZNF653 | c.1435G>A p.V479M | Missense Mutation (SNP) | VAF 108/222 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs749802000, COSV99541908; called by muse, mutect2, varscan2
- FAIM2 | c.559T>A p.S187T | Missense Mutation (SNP) | VAF 106/258 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); called by muse, varscan2
- RPL5 | c.238G>A p.A80T | Missense Mutation (SNP) | VAF 30/388 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.555); called by muse, mutect2
- SMARCA4 | c.3555A>T p.Q1185H | Missense Mutation (SNP) | VAF 113/317 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- ABCA3 | c.1902G>A p.K634= | Silent (SNP) | VAF 180/435 reads (41%) | called by muse, mutect2, varscan2
- KLHL29 | c.153C>T p.P51= | Silent (SNP) | VAF 74/196 reads (38%) | catalogued as rs898750963; called by muse, varscan2
- LACTBL1 | c.888C>T p.F296= (on ENST00000618559; = p.F341= on NM_001289974.2) | Silent (SNP) | VAF 201/501 reads (40%) | called by muse, mutect2, varscan2
- LMF1 | c.1638G>A p.P546= | Silent (SNP) | VAF 46/386 reads (12%) | catalogued as rs750316655, COSV51896177; called by muse, mutect2, varscan2
- ZAN | c.8283C>T p.G2761= | Silent (SNP) | VAF 37/338 reads (11%) | catalogued as rs371878327; called by muse, mutect2, varscan2
- ATP5MGL | c.-93A>T | 5'UTR (SNP) | VAF 10/44 reads (23%) | called by muse, varscan2
- GIMAP8 | c.*31_*32insAG | 3'UTR (INS) | VAF 125/210 reads (60%) | called by mutect2, pindel, varscan2
- PVRIG | chr7:100223977 C>T | 3'Flank (SNP) | VAF 526/661 reads (80%) | called by muse, mutect2, varscan2
- RNF24 | c.*2208C>T | 3'UTR (SNP) | VAF 88/229 reads (38%) | called by muse, mutect2
- XYLB | chr3:38421270 G>A | 3'Flank (SNP) | VAF 18/423 reads (4%) | catalogued as rs900297656; called by muse, mutect2
